Gene-level copy-number profile of tumor specimen SM-JU34G from CPTAC case C330255, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen SM-JU34G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a3542ac-df46-49df-8c50-04dbad8f4baf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105212 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/530f8197-7146-4c22-a063-18764a5d3111

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 27; copy number 2: 2,585; copy number 3: 1,760; copy number 4: 46,520; copy number 5: 275; copy number 6: 7,081; copy number 7: 12; copy number 8: 20; copy number 9: 16; copy number 10: 10; copy number 365: 2; copy number 409: 5.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:20,999,509–25,089,151, 72 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,335,386–42,657,190, 8 genes, copy number 10 (within-gene range 3–10): AC096540.1, RIMKLA, AL513331.1, ZMYND12, PPCS, CCDC30, RPS3AP11, TMSB4XP1.
- chr1:84,078,062–84,238,498, 1 gene, copy number 9 (within-gene range 3–9): PRKACB.
- chr1:84,244,334–84,690,803, 15 genes, copy number 9: NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, LINC01555, AC114482.1, SSX2IP.
- chr1:222,737,207–222,773,149, 2 genes, copy number 10: FAM177B, AL392172.1.
- chr7:54,621,025–55,211,628, 7 genes, copy number 365–409: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
